Somatic mutation profile of tumor specimen TCGA-CD-8533-01A (aliquot TCGA-CD-8533-01A-11D-2340-08) from TCGA case TCGA-CD-8533, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 48.8 years (17,821 days).
Specimen TCGA-CD-8533-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7503ceb-e07c-40cb-bfbe-2ed7a9342c0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-8533-10A (Blood Derived Normal), aliquot TCGA-CD-8533-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01f707d5-805b-4273-ae1a-1a79c7d60c7b

The open-access MAF lists 126 somatic variants for this specimen: 88 protein-altering or splice-affecting, 37 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 37, Nonsense Mutation 5, Frame Shift Del 4, 3'UTR 1, In Frame Ins 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MARS1 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 172/370 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777718, CM135382, COSV100007312; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 56/76 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AL121899.2 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 61/507 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs562802461, COSV101198436; called by muse, mutect2, varscan2
- ANO4 | c.1311G>C p.W437C (on ENST00000392977 / NM_001286615.2; = p.W402C on NM_178826.4) | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100153592, COSV54614380; called by muse, mutect2, varscan2
- ANXA13 | c.295A>G p.M99V | Missense Mutation (SNP) | VAF 54/337 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.577); catalogued as rs757903621, COSV99146090; called by muse, mutect2, varscan2
- AP1G2 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs972167499, COSV55337557; called by muse, mutect2, varscan2
- ASAP2 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); catalogued as COSV99856120; called by muse, mutect2, varscan2
- ASTN2 | c.589A>C p.I197L | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); catalogued as COSV100526812; called by muse, mutect2, varscan2
- ATP10A | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs763246380, CM1513003, COSV63520922; called by muse, mutect2, varscan2
- C1orf141 | c.160C>T p.L54F | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV100924330; called by muse, mutect2, varscan2
- CLVS2 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs750382549, COSV51562393, COSV51567732; called by muse, mutect2, varscan2
- CNR1 | c.1400C>T p.T467M | Missense Mutation (SNP) | VAF 110/446 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs138027855; called by muse, mutect2, varscan2
- COL4A6 | c.4363G>A p.G1455R | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772908962, COSV57866701; called by muse, mutect2, varscan2
- CSMD2 | c.3254G>A p.R1085H | Missense Mutation (SNP) | VAF 142/408 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs750515208, COSV53888438; called by muse, mutect2, varscan2
- CSNK1D | c.75C>T p.L25= | Splice Region (SNP) | VAF 25/31 reads (81%) | catalogued as rs1204199511, COSV100012376; called by muse, mutect2, varscan2
- DCAF12L2 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV100758584; called by muse, mutect2, varscan2
- DES | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1400200477, COSV100900406; called by muse, mutect2
- DLK2 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99767176; called by muse, mutect2, varscan2
- DMP1 | c.882C>A p.D294E | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as COSV99218682; called by muse, mutect2, varscan2
- DUOX2 | c.4229T>C p.L1410P | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV101199723; called by muse, mutect2, varscan2
- E2F8 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 9/271 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs924165322, COSV51465361; called by muse, mutect2
- EML2 | c.1510G>T p.G504C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99839973; called by muse, mutect2
- FBN2 | c.2756A>C p.E919A | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV99327054; called by muse, mutect2, varscan2
- FYB2 | c.617T>C p.L206S | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV100599503; called by muse, mutect2, varscan2
- GABRG1 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.79); catalogued as COSV99777903; called by muse, mutect2, varscan2
- GDF6 | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs764936321, COSV54623233, COSV54625391; called by muse, mutect2, varscan2
- H2AC15 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs752799977, COSV100356964; called by muse, mutect2, varscan2
- H3-3A | c.52A>G p.R18G | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV100831279; called by muse, mutect2, varscan2
- HECW1 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 45/282 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as rs776309881, COSV67830108, COSV67842023; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1966C>T p.R656* | Nonsense Mutation (SNP) | VAF 5/95 reads (5%) | catalogued as COSV54562747; called by muse, mutect2
- HYDIN | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs767319126, COSV55493204; called by muse, mutect2, varscan2
- IGDCC4 | c.1303G>A p.V435I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.696); catalogued as COSV61535413; called by muse, mutect2, varscan2
- ITGAL | c.1217A>G p.Y406C | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100776234; called by muse, mutect2, varscan2
- ITGB6 | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 56/172 reads (33%) | catalogued as COSV51792164, COSV99324476; called by muse, mutect2, varscan2
- KCNH5 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs138796167, COSV100526358; called by muse, mutect2, varscan2
- KNL1 | c.6766A>G p.M2256V (on ENST00000346991 / NM_170589.5; = p.M2230V on NM_144508.5) | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV100706385; called by muse, mutect2, varscan2
- KRT18 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.013); catalogued as rs1347876514, COSV101184010; called by muse, mutect2, varscan2
- LCTL | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100427205; called by muse, mutect2, varscan2
- LRFN5 | c.850T>A p.C284S | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99983591; called by muse, mutect2, varscan2
- LRP1B | c.4894C>T p.R1632* | Nonsense Mutation (SNP) | VAF 38/168 reads (23%) | catalogued as COSV67187956; called by muse, mutect2, varscan2
- MATN1 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs141354318; called by muse, mutect2, varscan2
- MINAR1 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 60/274 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100548854; called by muse, mutect2, varscan2
- MPHOSPH10 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as COSV99731108; called by muse, mutect2, varscan2
- MYBL2 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 140/1070 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as rs139167760; called by muse, mutect2, varscan2
- MYH3 | c.4897G>A p.A1633T | Missense Mutation (SNP) | VAF 93/306 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs374056469, COSV56860469; called by muse, mutect2, varscan2
- NEB | c.19273C>T p.R6425W | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs200165006; called by muse, mutect2, varscan2
- NINL | c.3244G>A p.D1082N | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.053); catalogued as rs780653118, COSV54001980; called by muse, mutect2, varscan2
- PNISR | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.059); catalogued as COSV100984345; called by muse, mutect2, varscan2
- PPP1R10 | c.2726G>A p.R909H | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV64739936; called by muse, mutect2, varscan2
- PREX2 | c.2117C>G p.T706S | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV99906810; called by muse, mutect2, varscan2
- PRR16 | c.196C>A p.Q66K (on ENST00000407149 / NM_001300783.2; = p.Q43K on NM_016644.2) | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV65406837; called by muse, mutect2, varscan2
- PSMC3 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 120/432 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV54080652; called by muse, mutect2, varscan2
- PZP | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs368845114; called by muse, mutect2, varscan2
- RAB5C | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100651410; called by muse, mutect2, varscan2
- RADIL | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771224463, COSV68200137; called by muse, mutect2, varscan2
- RND2 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 75/303 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1413062279, COSV99870011; called by muse, mutect2, varscan2
- RTL10 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs200764515; called by muse, mutect2, varscan2
- RYR2 | c.2943G>A p.M981I | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV100769823; called by muse, mutect2
- SIPA1L2 | c.1005G>C p.Q335H | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99478060; called by muse, mutect2, varscan2
- SIRPD | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 38/281 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs561939776, COSV101064901, COSV101064972; called by muse, mutect2, varscan2
- SLC1A6 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as rs999160649, COSV99693686; called by muse, mutect2, varscan2
- SLC7A2 | c.1612G>A p.V538I (on ENST00000494857 / NM_001370338.1; = p.V577I on NM_003046.6) | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs145522409; called by muse, mutect2, varscan2
- SOX3 | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV100983694; called by muse, mutect2, varscan2
- ST8SIA1 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 91/341 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV99682795; called by muse, mutect2, varscan2
- TBC1D8B | c.975T>A p.N325K | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99344298; called by muse, mutect2, varscan2
- TENM1 | c.5102C>T p.T1701M | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as rs377115628, COSV100949849; called by muse, mutect2, varscan2
- TLK1 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV100688054; called by muse, mutect2, varscan2
- TMEM143 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs750428394, COSV53155415, COSV99507203; called by muse, mutect2, varscan2
- TMEM63C | c.1315G>A p.V439I | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs765426661, COSV53603430; called by muse, mutect2, varscan2
- TNXB | c.3727C>T p.R1243W (on ENST00000647633; = p.R996W on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs775825339, COSV64476535; called by muse, mutect2, varscan2
- TRPC6 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); catalogued as rs200031940; called by muse, mutect2, varscan2
- TTN | c.77660G>A p.R25887Q (on ENST00000591111; = p.R18463Q on NM_003319.4) | Missense Mutation (SNP) | VAF 53/207 reads (26%) | PolyPhen possibly damaging (0.579); catalogued as rs765230578, COSV100610307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ULK1 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as rs200272214; called by muse, mutect2, varscan2
- ULK4 | c.1784C>G p.P595R | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as rs765156864, COSV100092226; called by muse, mutect2, varscan2
- USP34 | c.10379C>A p.T3460N | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV100816006; called by muse, mutect2, varscan2
- USP37 | c.2641G>T p.E881* | Nonsense Mutation (SNP) | VAF 89/216 reads (41%) | catalogued as COSV99294365; called by muse, mutect2, varscan2
- UTP25 | c.191G>C p.S64T | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV101530950; called by muse, mutect2, varscan2
- WASHC2A | c.3539G>A p.S1180N | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV99254614; called by muse, mutect2, varscan2
- YTHDC2 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as COSV99363196; called by muse, mutect2, varscan2
- ZNF385B | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV100415996; called by muse, mutect2, varscan2
- ZNF831 | c.1331C>T p.T444M | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64038766; called by muse, mutect2, varscan2
- ZNF880 | c.855T>A p.N285K | Missense Mutation (SNP) | VAF 79/123 reads (64%) | SIFT tolerated (0.93); PolyPhen benign (0.018); catalogued as rs1377495110, COSV101424950; called by muse, mutect2, varscan2
- EIF3A | c.2556del p.E853Kfs*320 | Frame Shift Del (DEL) | VAF 147/491 reads (30%) | called by mutect2, pindel, varscan2
- GLG1 | c.2422del p.E808Rfs*5 | Frame Shift Del (DEL) | VAF 15/86 reads (17%) | called by mutect2, pindel, varscan2
- MICALL2 | c.2002del p.A668Pfs*57 | Frame Shift Del (DEL) | VAF 64/129 reads (50%) | called by mutect2, pindel, varscan2
- NDUFS3 | c.95_97del p.L32del | In Frame Del (DEL) | VAF 31/166 reads (19%) | called by pindel, varscan2
- VPS13B | c.4426_4428dup p.K1476dup | In Frame Ins (INS) | VAF 89/185 reads (48%) | called by pindel, varscan2
- ZNF189 | c.1684_1705del p.H562Sfs*25 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | called by mutect2, pindel, varscan2
- ABCG5 | c.234C>T p.S78= | Silent (SNP) | VAF 33/228 reads (14%) | catalogued as rs748628439, COSV53209401, COSV53209655; called by muse, mutect2, varscan2
- ADAM22 | c.216G>A p.T72= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV55973136, COSV99716640; called by muse, mutect2
- AMOTL1 | c.2688C>T p.R896= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs955128227, COSV58565711; called by muse, mutect2, varscan2
- ASMTL | c.795G>A p.A265= | Silent (SNP) | VAF 41/175 reads (23%) | catalogued as rs756485060, COSV101187744; called by muse, mutect2, varscan2
- BEND7 | c.711C>T p.D237= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as rs765934614, COSV100347093, COSV61990366; called by muse, mutect2, varscan2
- CPSF1 | c.3654C>T p.V1218= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100450380; called by muse, mutect2, varscan2
- CSF2RA | c.741G>A p.S247= | Silent (SNP) | VAF 49/236 reads (21%) | catalogued as rs761160075, COSV100817685, COSV62627212; called by muse, mutect2, varscan2
- CUBN | c.909C>T p.C303= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as rs543709109, COSV64707159; called by muse, mutect2, varscan2
- DDR1 | c.1314C>G p.L438= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100241457, COSV61323667; called by muse, mutect2, varscan2
- DIRAS3 | c.552C>T p.T184= | Silent (SNP) | VAF 38/168 reads (23%) | catalogued as COSV100921311; called by muse, mutect2, varscan2
- DPP9 | c.1866C>T p.Y622= (on ENST00000598800; = p.Y651= on NM_139159.5) | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs759064053, COSV99506058; called by muse, mutect2, varscan2
- EIF5 | c.1050C>T p.V350= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as COSV99384777; called by muse, mutect2
- ELSPBP1 | c.522C>T p.S174= | Silent (SNP) | VAF 61/232 reads (26%) | catalogued as rs779023687, COSV60413494; called by muse, mutect2, varscan2
- FLG | c.4365C>T p.H1455= | Silent (SNP) | VAF 106/553 reads (19%) | catalogued as rs142950612; called by muse, mutect2, varscan2
- GOLGA4 | c.6339A>G p.A2113= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100728848, COSV100729090; called by muse, mutect2, varscan2
- GPC6 | c.1233C>T p.S411= | Silent (SNP) | VAF 60/677 reads (9%) | catalogued as rs368011430, COSV65539642; called by muse, mutect2
- HSPA13 | c.1173A>G p.E391= | Silent (SNP) | VAF 54/267 reads (20%) | catalogued as COSV99580004; called by muse, mutect2, varscan2
- LRIF1 | c.594G>A p.A198= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs1452856559, COSV100870833; called by muse, mutect2, varscan2
- MYRF | c.2634C>T p.S878= (on ENST00000278836 / NM_001127392.3; = p.S843= on NM_013279.4) | Silent (SNP) | VAF 52/209 reads (25%) | catalogued as rs777273339, COSV99606979; called by muse, mutect2, varscan2
- NCKAP1 | c.735C>T p.S245= | Silent (SNP) | VAF 36/132 reads (27%) | catalogued as rs200320828, COSV100720565; called by muse, mutect2, varscan2
- NPAS4 | c.1092C>T p.T364= | Silent (SNP) | VAF 85/425 reads (20%) | catalogued as rs1210861366, COSV60650653; called by muse, mutect2, varscan2
- NR4A3 | c.72G>A p.S24= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV58249192; called by muse, mutect2, varscan2
- OR2A1 | c.327C>T p.S109= | Silent (SNP) | VAF 35/287 reads (12%) | catalogued as rs758974110, COSV68822763; called by muse, mutect2, varscan2
- OR6Y1 | c.357T>A p.L119= | Silent (SNP) | VAF 13/232 reads (6%) | catalogued as COSV100225351; called by muse, mutect2
- PCDH11Y | c.624C>T p.Y208= (on ENST00000400457 / NM_032973.2; = p.Y197= on NM_032971.3) | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV53093974; called by muse, mutect2, varscan2
- PDPR | c.1539A>G p.E513= | Silent (SNP) | VAF 35/234 reads (15%) | catalogued as COSV99848182; called by muse, mutect2, varscan2
- PPBP | c.222C>T p.P74= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as rs781700993, COSV99933010; called by muse, mutect2, varscan2
- RAB4A | c.636C>T p.N212= | Silent (SNP) | VAF 62/293 reads (21%) | catalogued as rs748859511, COSV100796992; called by muse, mutect2, varscan2
- SERPINB13 | c.423C>T p.A141= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as rs150453343; called by muse, mutect2, varscan2
- STX11 | c.666C>T p.R222= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as rs768064993, COSV100845483; called by muse, mutect2, varscan2
- TMEM132B | c.1833G>A p.P611= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs757659675, COSV54769887; called by muse, mutect2, varscan2
- TNR | c.3913C>A p.R1305= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs778628919, COSV54896002, COSV99689299; called by muse, mutect2, varscan2
- TNRC18 | c.3267G>A p.P1089= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as rs757774419, COSV101269557; called by muse, mutect2, varscan2
- TRIML2 | c.984G>A p.K328= | Silent (SNP) | VAF 77/256 reads (30%) | catalogued as rs778809487, COSV100456041; called by muse, mutect2, varscan2
- UGT3A2 | c.354G>A p.A118= | Silent (SNP) | VAF 32/193 reads (17%) | catalogued as rs191531345; called by muse, mutect2, varscan2
- VCAN | c.9732A>G p.T3244= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV99425562; called by muse, mutect2, varscan2
- ZNF517 | c.1272C>T p.F424= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV63465364; called by muse, mutect2, varscan2
- SLC26A9 | c.*234_*244del | 3'UTR (DEL) | VAF 20/128 reads (16%) | called by mutect2, pindel
